Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3578, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3578-01A (Primary Tumor).

Diagnosis/ diagnoses:

1. Tumor-free splenectomy preparation with recent capsule and parenchymal defects.
2. Resected colon and rectum show tumor-free resection margins and the inclusion of a moderately differentiated mucinous adenocarcinoma clearly growing on the base of a pre-existing tubulovillous adenoma, with infiltration of the perimuscular fatty tissue at a depth of 2 mm and without regional lymph node metastases (G2, pT3, pN0 0/25 L0 V0 R0).

Source: NCI Genomic Data Commons file 947e23df-bc97-43dc-9a1c-1f2cd36f8165 (TCGA-AG-3578.C0D92B00-A693-4BDE-868F-E9C322DF4FDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).